Somatic mutation profile of tumor specimen TCGA-OR-A5JD-01A (aliquot TCGA-OR-A5JD-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JD, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 57.5 years (20,989 days).
Specimen TCGA-OR-A5JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea909dd4-6c04-43b6-8d11-68bf265a4461.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JD-10B (Blood Derived Normal), aliquot TCGA-OR-A5JD-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6921cea5-f3ff-4f30-9486-662ceec66327

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 4, 3'Flank 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF4 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 201/284 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs539627686; called by muse, mutect2, varscan2
- DNAJC13 | c.6326C>G p.A2109G | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.941); catalogued as rs758424341; called by muse, mutect2, varscan2
- FBXO8 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1355328520; called by muse, mutect2, varscan2
- KLHDC8B | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1279064899; called by muse, mutect2, varscan2
- MARCHF4 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56105311; called by muse, mutect2, varscan2
- SLC25A37 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1416365861, COSV99264237; called by muse, mutect2, varscan2
- STOX1 | c.878G>A p.C293Y | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs745801979; called by muse, mutect2, varscan2
- ARMC5 | c.1921del p.A641Pfs*2 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ARMCX1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ATP11C | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, varscan2
- CHMP4C | c.408dup p.E137Rfs*21 | Frame Shift Ins (INS) | VAF 57/183 reads (31%) | called by mutect2, pindel, varscan2
- FUT3 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNG4 | c.68G>C p.W23S | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIFC3 | c.2432C>T p.T811I | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- MXRA5 | c.6911T>A p.F2304Y | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUP155 | c.1831G>A p.G611S (on ENST00000231498 / NM_153485.3; = p.G552S on NM_004298.4) | Missense Mutation (SNP) | VAF 19/625 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- PLXNB3 | c.1620G>C p.E540D | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, varscan2
- SLC25A37 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- STAB1 | c.5726G>T p.W1909L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUT4 | c.1915T>C p.F639L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ZNF229 | c.1793G>C p.R598T | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZNF394 | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSNK2A2 | c.796C>T p.L266= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as rs780524052; called by muse, mutect2, varscan2
- EXOC1 | c.789C>T p.N263= | Silent (SNP) | VAF 80/178 reads (45%) | called by muse, mutect2, varscan2
- FRY | c.5776T>C p.L1926= | Silent (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- HOXD4 | c.405C>A p.P135= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100106661; called by muse, mutect2, varscan2
- COPS9 | chr2:240126615 G>T | 3'Flank (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- ZNF271P | n.1056A>G | RNA (SNP) | VAF 25/34 reads (74%) | catalogued as rs1480869973; called by muse, mutect2, varscan2
